Somatic mutation profile of tumor specimen HCM-CSHL-1266-C20-06A (aliquot HCM-CSHL-1266-C20-06A-11D-A882-36) from HCMI case HCM-CSHL-1266-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 34.7 years (12,684 days).
Specimen HCM-CSHL-1266-C20-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a0aa27e-2925-431a-9c3e-bf564cdd6cfe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-1266-C20-11A (Solid Tissue Normal), aliquot HCM-CSHL-1266-C20-11A-01D-A882-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21ca3223-1075-4310-8a45-44132e415fc1

The open-access MAF lists 141 somatic variants for this specimen: 98 protein-altering or splice-affecting, 40 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 40, Nonsense Mutation 9, Frame Shift Del 3, Translation Start Site 2, In Frame Del 2, Frame Shift Ins 2, Splice Region 1, 3'Flank 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 455/495 reads (92%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AL592490.1 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 99/584 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV69425032; called by muse, mutect2, varscan2
- ARHGEF28 | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs1298080364, COSV104383102; called by muse, varscan2
- ATF5 | c.500G>T p.R167L | Missense Mutation (SNP) | VAF 73/350 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.02); catalogued as rs531308133; called by muse, mutect2, varscan2
- CACNA1B | c.4376C>T p.S1459L | Missense Mutation (SNP) | VAF 177/562 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.636); catalogued as rs775488955, COSV53149897; called by muse, mutect2, varscan2
- CLCN4 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 135/166 reads (81%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.856); catalogued as COSV66466160; called by muse, mutect2, varscan2
- COL5A2 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 142/336 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs983377642, COSV66410763; called by muse, mutect2, varscan2
- CSMD3 | c.2876C>A p.S959* (on ENST00000297405 / NM_001363185.1; = p.S855* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 133/484 reads (27%) | catalogued as COSV52287772; called by muse, mutect2, varscan2
- EEF1A2 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 100/1016 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as rs1325353717, COSV53207183; ClinVar: uncertain significance; called by muse, mutect2
- ENTPD4 | c.1644C>A p.F548L | Missense Mutation (SNP) | VAF 76/245 reads (31%) | SIFT tolerated (0.91); PolyPhen benign (0.006); catalogued as COSV62268138; called by muse, mutect2, varscan2
- FAT3 | c.8505A>T p.Q2835H | Missense Mutation (SNP) | VAF 233/485 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99969150; called by muse, mutect2, varscan2
- GABRA5 | c.751T>G p.F251V | Missense Mutation (SNP) | VAF 127/329 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59475409; called by muse, mutect2, varscan2
- GALNT9 | c.478G>A p.V160I | Missense Mutation (SNP) | VAF 281/324 reads (87%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as rs1486896844; called by muse, mutect2, varscan2
- GPR158 | c.3370G>T p.A1124S | Missense Mutation (SNP) | VAF 396/437 reads (91%) | SIFT tolerated (0.47); PolyPhen benign (0.024); catalogued as rs1047586610, COSV66267663; called by muse, mutect2, varscan2
- GRIN2C | c.1859C>T p.P620L | Missense Mutation (SNP) | VAF 115/528 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751104229; called by muse, mutect2, varscan2
- HECW1 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 280/722 reads (39%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.37); catalogued as rs754513729, COSV67825760, COSV67831887; called by muse, mutect2, varscan2
- HELZ2 | c.2506G>A p.G836S (on ENST00000467148 / NM_001037335.2; = p.G267S on NM_033405.3) | Missense Mutation (SNP) | VAF 58/646 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1203692082; called by muse, mutect2
- IGHG3 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 208/505 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.165); catalogued as rs745813727; called by muse, mutect2, varscan2
- LATS1 | c.800C>A p.S267* | Nonsense Mutation (SNP) | VAF 243/406 reads (60%) | catalogued as COSV53588519; called by muse, mutect2, varscan2
- LRIF1 | c.2014A>G p.T672A | Missense Mutation (SNP) | VAF 403/429 reads (94%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs775682328; called by muse, mutect2, varscan2
- LRRC69 | c.325T>G p.L109V | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1428918343; called by muse, mutect2, varscan2
- MASP1 | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 146/256 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs760110023; called by muse, varscan2
- MFAP3L | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 145/177 reads (82%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.831); catalogued as rs200622205, COSV64372678; called by muse, mutect2, varscan2
- MUC16 | c.11376G>A p.M3792I | Missense Mutation (SNP) | VAF 201/424 reads (47%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as rs754905495; called by muse, mutect2, varscan2
- OR10C1 | c.534C>A p.F178L (on ENST00000622521; = p.F176L on NM_013941.3) | Missense Mutation (SNP) | VAF 258/683 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as rs1215726941, COSV65822546; called by muse, mutect2, varscan2
- PC | c.1867C>A p.P623T | Missense Mutation (SNP) | VAF 86/386 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67369447; called by muse, mutect2, varscan2
- PCDH17 | c.2128G>A p.V710M | Missense Mutation (SNP) | VAF 90/620 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV100931497; called by muse, mutect2, varscan2
- PCDHGA10 | c.2161C>T p.R721W | Missense Mutation (SNP) | VAF 457/803 reads (57%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.031); catalogued as rs746539261, COSV99540054; called by muse, mutect2, varscan2
- PDPR | c.1361G>A p.G454D | Missense Mutation (SNP) | VAF 100/382 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs957183542; called by muse, mutect2, varscan2
- PPIL2 | c.1148C>T p.T383M | Missense Mutation (SNP) | VAF 54/372 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs769760032; called by muse, mutect2, varscan2
- PPP4R4 | c.2611T>A p.S871T | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.969); catalogued as rs750925625; called by mutect2, varscan2
- RBMXL3 | c.2347C>T p.R783* | Nonsense Mutation (SNP) | VAF 158/538 reads (29%) | catalogued as rs1373914939, COSV100407349; called by muse, mutect2, varscan2
- ROBO2 | c.1482T>G p.S494R | Missense Mutation (SNP) | VAF 55/194 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs13060040; called by muse, mutect2, varscan2
- RYR3 | c.3298C>T p.R1100* | Nonsense Mutation (SNP) | VAF 228/501 reads (46%) | catalogued as rs1297136189; called by muse, mutect2, varscan2
- SCN1A | c.5822C>T p.T1941M (on ENST00000303395 / NM_001202435.3; = p.T1930M on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/207 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0.075); catalogued as rs756845310, COSV57660387; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEC62 | c.1054C>T p.R352* | Nonsense Mutation (SNP) | VAF 94/283 reads (33%) | catalogued as rs141360935; called by muse, mutect2, varscan2
- SLC22A2 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 641/697 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1314319598, COSV65266636; called by muse, mutect2, varscan2
- SLC22A8 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 94/472 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); catalogued as rs769079351; called by muse, mutect2, varscan2
- SLC24A5 | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 174/419 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs1312635224, COSV58316551; called by muse, mutect2, varscan2
- SLITRK5 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 79/850 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs144076922, COSV100280998; called by muse, mutect2
- SRRM2 | c.2632G>A p.D878N | Missense Mutation (SNP) | VAF 151/287 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.034); catalogued as rs745979288; called by muse, mutect2, varscan2
- SYNE1 | c.10730A>C p.Q3577P (on ENST00000367255 / NM_182961.4; = p.Q3584P on NM_033071.3) | Missense Mutation (SNP) | VAF 281/474 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs757925072; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TCAF1 | c.2281C>T p.R761C | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs775955914; called by mutect2, varscan2
- TGM5 | c.1412G>T p.G471V (on ENST00000220420 / NM_201631.4; = p.G389V on NM_004245.4) | Missense Mutation (SNP) | VAF 26/438 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.368); catalogued as COSV55008995; called by muse, mutect2
- TIAM1 | c.1652C>T p.A551V | Missense Mutation (SNP) | VAF 78/284 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs970048985, COSV99732887; called by muse, mutect2, varscan2
- WDR41 | c.1262C>T p.T421M | Missense Mutation (SNP) | VAF 54/225 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs776842528, COSV53737342; called by muse, mutect2, varscan2
- ZBTB43 | c.662A>C p.D221A | Missense Mutation (SNP) | VAF 322/618 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0.206); catalogued as rs771306645, COSV65094936; called by muse, varscan2
- ZC3H3 | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 740/1121 reads (66%) | catalogued as rs764083420; called by muse, mutect2, varscan2
- ZC3H4 | c.2384G>A p.R795Q | Missense Mutation (SNP) | VAF 90/299 reads (30%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.723); catalogued as rs1369711181; called by muse, mutect2, varscan2
- ZFYVE9 | c.3113C>G p.S1038C | Missense Mutation (SNP) | VAF 65/236 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs192873630; called by muse, mutect2, varscan2
- ZNF25 | c.176A>G p.K59R | Missense Mutation (SNP) | VAF 17/269 reads (6%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.681); catalogued as rs937732033; called by muse, mutect2
- ZNF84 | c.781A>G p.K261E | Missense Mutation (SNP) | VAF 256/297 reads (86%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs944613069; called by muse, mutect2, varscan2
- ABHD14B | c.422A>C p.K141T | Missense Mutation (SNP) | VAF 246/300 reads (82%) | SIFT tolerated (0.08); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- AJUBA | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 338/801 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- AL031777.2 | c.190C>G p.L64V | Missense Mutation (SNP) | VAF 160/384 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ALG5 | c.11_19del p.L4_L6del | In Frame Del (DEL) | VAF 138/622 reads (22%) | called by mutect2, pindel, varscan2
- ANXA8 | c.937G>A p.G313S | Missense Mutation (SNP) | VAF 273/530 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APC | c.4055_4064delinsAT p.V1352Dfs*20 | Frame Shift Del (DEL) | VAF 244/289 reads (84%) | called by pindel, varscan2*
- AQR | c.1406A>T p.N469I | Missense Mutation (SNP) | VAF 119/254 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARL14EP | c.28C>A p.Q10K | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- ASTN1 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 74/172 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- C2orf16 | c.3665C>T p.S1222F | Missense Mutation (SNP) | VAF 108/436 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- CASZ1 | c.2843C>G p.P948R | Missense Mutation (SNP) | VAF 114/425 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- CCDC88B | c.3469_3470delinsT p.E1157Cfs*63 | Frame Shift Del (DEL) | VAF 102/630 reads (16%) | called by pindel, varscan2*
- CPN2 | c.286C>A p.L96M | Missense Mutation (SNP) | VAF 106/347 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DGKA | c.817G>A p.V273M | Missense Mutation (SNP) | VAF 73/339 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- DPM1 | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 52/515 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EPB41L5 | c.1421T>G p.M474R | Missense Mutation (SNP) | VAF 194/465 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.014); called by muse, mutect2
- FAM76A | c.840C>A p.A280= | Splice Region (SNP) | VAF 29/105 reads (28%) | called by muse, mutect2, varscan2
- FUT4 | c.257C>G p.S86C | Missense Mutation (SNP) | VAF 406/885 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- GEMIN6 | c.394del p.V132Sfs*2 | Frame Shift Del (DEL) | VAF 114/540 reads (21%) | called by mutect2, pindel, varscan2
- GLYATL3 | c.753_755del p.D252del | In Frame Del (DEL) | VAF 165/438 reads (38%) | called by mutect2, pindel, varscan2
- HOXA7 | c.56C>A p.S19Y | Missense Mutation (SNP) | VAF 206/598 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- IKZF2 | c.1369A>G p.I457V | Missense Mutation (SNP) | VAF 127/333 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IRS4 | c.1384G>C p.G462R | Missense Mutation (SNP) | VAF 259/392 reads (66%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.031); called by muse, varscan2
- LAMC3 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 292/578 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- LRRFIP1 | c.693A>T p.Q231H (on ENST00000392000 / NM_001137552.2; = p.Q207H on NM_004735.4) | Missense Mutation (SNP) | VAF 218/471 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MOV10 | c.246G>A p.W82* | Nonsense Mutation (SNP) | VAF 20/728 reads (3%) | called by muse, mutect2
- ODF2 | c.2485G>A p.A829T (on ENST00000434106 / NM_153433.2; = p.A805T on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 124/328 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR4C12 | c.554T>C p.L185P | Missense Mutation (SNP) | VAF 214/329 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH15 | c.5669C>A p.A1890E | Missense Mutation (SNP) | VAF 185/217 reads (85%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- PITPNM2 | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 388/434 reads (89%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.849); called by muse, varscan2
- PNISR | c.1619C>G p.S540* | Nonsense Mutation (SNP) | VAF 83/189 reads (44%) | called by muse, mutect2, varscan2
- POGLUT1 | c.1115A>G p.Y372C | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- PTBP3 | c.1069A>C p.N357H | Missense Mutation (SNP) | VAF 110/307 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RIC1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 75/219 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- SMG7 | c.2686C>G p.R896G | Missense Mutation (SNP) | VAF 23/380 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.069); called by muse, mutect2
- STEAP2 | c.1275A>C p.R425S | Missense Mutation (SNP) | VAF 54/219 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- TAF1A | c.1261A>G p.I421V | Missense Mutation (SNP) | VAF 129/143 reads (90%) | SIFT tolerated (0.99); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TEPSIN | c.1383C>A p.S461R | Missense Mutation (SNP) | VAF 56/818 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2
- TFPI | c.208T>C p.F70L | Missense Mutation (SNP) | VAF 92/216 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- TRPC4 | c.2042A>G p.K681R | Missense Mutation (SNP) | VAF 24/456 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- TSHZ3 | c.1969G>T p.E657* | Nonsense Mutation (SNP) | VAF 159/598 reads (27%) | called by muse, mutect2, varscan2
- USP48 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 59/207 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ZBED4 | c.1940A>C p.K647T | Missense Mutation (SNP) | VAF 201/333 reads (60%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.702); called by muse, varscan2
- ZNF84 | c.1701dup p.E568Rfs*5 | Frame Shift Ins (INS) | VAF 65/264 reads (25%) | called by mutect2, varscan2
- ZNF84 | c.1707dup p.P570Tfs*3 | Frame Shift Ins (INS) | VAF 69/366 reads (19%) | called by mutect2*, pindel, varscan2*
- ZNF888 | c.634A>C p.K212Q | Missense Mutation (SNP) | VAF 88/141 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ANK3 | c.3009C>T p.H1003= (on ENST00000280772 / NM_001320874.2; = p.H137= on NM_001149.3) | Silent (SNP) | VAF 383/421 reads (91%) | catalogued as rs147312170; called by muse, varscan2
- AP2A2 | c.534G>A p.T178= | Silent (SNP) | VAF 268/352 reads (76%) | catalogued as rs757988092; called by muse, mutect2, varscan2
- ATP13A4 | c.3549T>G p.S1183= | Silent (SNP) | VAF 66/224 reads (29%) | catalogued as COSV61321448; called by muse, mutect2, varscan2
- BGN | c.615C>T p.F205= | Silent (SNP) | VAF 92/332 reads (28%) | catalogued as rs935930397, COSV59036001; called by muse, mutect2, varscan2
- C17orf49 | c.159T>A p.A53= | Silent (SNP) | VAF 21/384 reads (5%) | called by muse, mutect2
- CCDC178 | c.6T>C p.T2= | Silent (SNP) | VAF 36/67 reads (54%) | called by muse, mutect2, varscan2
- CHSY3 | c.126C>T p.S42= | Silent (SNP) | VAF 580/625 reads (93%) | called by muse, mutect2, varscan2
- CTNNBIP1 | c.108C>T p.S36= | Silent (SNP) | VAF 106/353 reads (30%) | catalogued as rs765598833, COSV101032904; called by muse, mutect2, varscan2
- DAGLB | c.1479G>T p.G493= | Silent (SNP) | VAF 161/490 reads (33%) | called by muse, mutect2, varscan2
- ELF1 | c.573G>A p.T191= | Silent (SNP) | VAF 93/340 reads (27%) | catalogued as rs138849972; called by muse, mutect2, varscan2
- ERI2 | c.273A>G p.E91= | Silent (SNP) | VAF 130/216 reads (60%) | called by muse, mutect2, varscan2
- EXT1 | c.1839G>A p.T613= | Silent (SNP) | VAF 34/684 reads (5%) | catalogued as rs765677175; ClinVar: likely benign; called by muse, mutect2
- FBXW7 | c.1959G>A p.T653= (on ENST00000281708 / NM_001349798.2; = p.T573= on NM_018315.5) | Silent (SNP) | VAF 86/258 reads (33%) | catalogued as rs767500139, COSV55899122, COSV55917020; called by muse, mutect2, varscan2
- GABBR1 | c.504C>T p.R168= | Silent (SNP) | VAF 404/852 reads (47%) | catalogued as rs1049475813; called by muse, mutect2, varscan2
- GABRA6 | c.1221C>A p.L407= | Silent (SNP) | VAF 35/649 reads (5%) | called by muse, mutect2
- GAL3ST4 | c.1323T>C p.S441= | Silent (SNP) | VAF 72/422 reads (17%) | called by muse, mutect2, varscan2
- HEATR1 | c.1659G>T p.T553= | Silent (SNP) | VAF 48/135 reads (36%) | catalogued as rs775414720, COSV63983406; called by muse, mutect2, varscan2
- KCNT1 | c.2634G>A p.A878= (on ENST00000488444; = p.A897= on NM_020822.3) | Silent (SNP) | VAF 174/348 reads (50%) | catalogued as rs142642528; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- KDM6A | c.2709A>C p.L903= | Silent (SNP) | VAF 36/41 reads (88%) | called by muse, varscan2
- KLHL11 | c.1995C>T p.Y665= | Silent (SNP) | VAF 152/391 reads (39%) | called by muse, mutect2, varscan2
- MAP7D3 | c.2406A>T p.P802= | Silent (SNP) | VAF 97/324 reads (30%) | called by muse, mutect2, varscan2
- MUC16 | c.20460A>G p.L6820= | Silent (SNP) | VAF 151/337 reads (45%) | called by muse, mutect2, varscan2
- NAALAD2 | c.573T>C p.V191= | Silent (SNP) | VAF 88/175 reads (50%) | called by muse, mutect2, varscan2
- NPAP1 | c.75C>T p.P25= | Silent (SNP) | VAF 287/662 reads (43%) | catalogued as rs776835685, COSV61508007; called by muse, mutect2, varscan2
- NUSAP1 | c.414C>T p.D138= | Silent (SNP) | VAF 154/359 reads (43%) | catalogued as rs747528263; called by muse, mutect2, varscan2
- OR10A5 | c.231C>A p.V77= | Silent (SNP) | VAF 24/335 reads (7%) | catalogued as rs1388234826; called by muse, mutect2
- PCDH11X | c.39G>A p.L13= | Silent (SNP) | VAF 273/296 reads (92%) | called by muse, mutect2, varscan2
- PPIL2 | c.1056C>T p.D352= | Silent (SNP) | VAF 92/530 reads (17%) | catalogued as rs751394220, COSV58606243; called by muse, mutect2, varscan2
- SGSM1 | c.2649G>A p.A883= (on ENST00000400359 / NM_001039948.4; = p.A822= on NM_133454.3) | Silent (SNP) | VAF 276/514 reads (54%) | catalogued as rs770834809; called by muse, varscan2
- SHANK1 | c.93C>T p.D31= | Silent (SNP) | VAF 310/489 reads (63%) | catalogued as rs764205732, COSV99520023; called by muse, mutect2, varscan2
- SLC45A1 | c.1572C>A p.R524= | Silent (SNP) | VAF 104/383 reads (27%) | called by muse, mutect2, varscan2
- SPATA31A1 | c.2739T>G p.P913= | Silent (SNP) | VAF 56/348 reads (16%) | called by muse, mutect2, varscan2
- TNRC6C | c.2148G>A p.P716= | Silent (SNP) | VAF 166/478 reads (35%) | catalogued as rs768647250; called by muse, mutect2, varscan2
- TRIM72 | c.1311G>A p.P437= | Silent (SNP) | VAF 258/448 reads (58%) | catalogued as rs1224431203; called by muse, mutect2, varscan2
- TSPAN13 | c.111C>T p.F37= | Silent (SNP) | VAF 64/431 reads (15%) | catalogued as rs757952595; called by muse, mutect2, varscan2
- TTN | c.21396A>G p.Q7132= (on ENST00000591111; = p.Q6205= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 107/257 reads (42%) | catalogued as COSV60190155; called by muse, mutect2, varscan2
- UBC | c.177C>T p.Y59= | Silent (SNP) | VAF 210/607 reads (35%) | catalogued as rs11537757; called by muse, mutect2, varscan2
- VCAM1 | c.681T>A p.V227= | Silent (SNP) | VAF 12/230 reads (5%) | called by muse, mutect2
- XRN1 | c.168A>T p.S56= | Silent (SNP) | VAF 11/199 reads (6%) | called by muse, mutect2
- ZNF687 | c.3636T>C p.P1212= | Silent (SNP) | VAF 16/428 reads (4%) | called by muse, mutect2
- BOLL | c.*1G>C | 3'UTR (SNP) | VAF 34/289 reads (12%) | called by muse, mutect2, varscan2
- OSCP1 | c.546+3475C>T | Intron (SNP) | VAF 39/118 reads (33%) | catalogued as rs1184541687; called by mutect2, varscan2
- PTPRU | chr1:29325739 C>T | 3'Flank (SNP) | VAF 262/471 reads (56%) | catalogued as rs765826238; called by muse, mutect2, varscan2
